Somatic mutation profile of tumor specimen C3N-02033-03 (aliquot CPT0133960009) from CPTAC case C3N-02033, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 76.8 years (28,057 days).
Specimen C3N-02033-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65c71e74-f0ca-4687-b8bb-681635ab84f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02033-71 (Blood Derived Normal), aliquot CPT0134060002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21858726-9575-4574-93a2-8c3903121561

The open-access MAF lists 512 somatic variants for this specimen: 310 protein-altering or splice-affecting, 182 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 284, Silent 182, Nonsense Mutation 19, Intron 10, Splice Site 4, RNA 3, 3'UTR 2, 3'Flank 2, 5'Flank 2, Splice Region 2, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD2 | c.1958G>A p.G653E | Missense Mutation (SNP) | VAF 87/292 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.045); catalogued as COSV58050066, COSV58051493; called by muse, mutect2, varscan2
- ACAN | c.2596G>A p.V866I | Missense Mutation (SNP) | VAF 46/692 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.116); catalogued as rs776186236; called by muse, mutect2
- ACSM5 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 120/298 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776309636, COSV59375732; called by muse, mutect2, varscan2
- ACSS3 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 107/297 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759012460, COSV54086149; called by muse, mutect2, varscan2
- ACTC1 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 104/402 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV51759315; called by muse, mutect2, varscan2
- ADAM28 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 491/769 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.181); catalogued as COSV56103179, COSV56103757; called by muse, mutect2, varscan2
- ADAMTS20 | c.1597G>A p.D533N | Missense Mutation (SNP) | VAF 125/310 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs761063670; called by muse, mutect2, varscan2
- ADAMTS3 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); catalogued as rs759533507, COSV54404466; called by muse, mutect2, varscan2
- ADGRL2 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 133/363 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99587333; called by muse, mutect2, varscan2
- AGXT | c.847-1G>A p.X283_splice | Splice Site (SNP) | VAF 115/355 reads (32%) | catalogued as CS001404, CS154499, COSV100280207; called by muse, mutect2, varscan2
- AHNAK | c.1703G>A p.R568K | Missense Mutation (SNP) | VAF 106/305 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs902388227; called by muse, mutect2, varscan2
- AHNAK2 | c.13594C>T p.P4532S | Missense Mutation (SNP) | VAF 204/550 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV60924482; called by muse, mutect2
- AKAP9 | c.11206C>T p.R3736* (on ENST00000359028; = p.R3712* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 230/421 reads (55%) | catalogued as rs1234676587, COSV62354774; called by muse, mutect2, varscan2
- ANKS1B | c.3095C>T p.T1032I (on ENST00000547776 / NM_152788.4; = p.T198I on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 136/339 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1387279424; called by muse, mutect2, varscan2
- ANO4 | c.545G>A p.R182K (on ENST00000392977 / NM_001286615.2; = p.R147K on NM_178826.4) | Missense Mutation (SNP) | VAF 96/273 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.287); catalogued as rs1366180874, COSV54588244; called by muse, mutect2, varscan2
- APLNR | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 167/549 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762740856; called by muse, mutect2, varscan2
- ARMH4 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 134/345 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs765053233; called by muse, mutect2, varscan2
- AXL | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 122/401 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV56568572; called by muse, mutect2, varscan2
- BCAS4 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 140/433 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.056); catalogued as rs1302298614; called by muse, mutect2, varscan2
- BRINP3 | c.1647G>A p.M549I | Missense Mutation (SNP) | VAF 141/726 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.38); catalogued as rs1557963299, COSV66520672; called by muse, mutect2, varscan2
- CACNA1E | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 96/634 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as rs78231578, COSV62405482; called by muse, mutect2, varscan2
- CASZ1 | c.4262C>T p.S1421F | Missense Mutation (SNP) | VAF 180/516 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100984814, COSV65458422; called by muse, mutect2, varscan2
- CASZ1 | c.2852C>T p.S951L | Missense Mutation (SNP) | VAF 185/472 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.242); catalogued as COSV59732548, COSV59734201; called by muse, mutect2, varscan2
- CCDC38 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 73/177 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV60183131; called by muse, mutect2, varscan2
- CCDC60 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 83/233 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as rs764208425, COSV59540294; called by muse, mutect2, varscan2
- CD209 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 214/654 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as rs770992849; called by muse, varscan2
- CDH19 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 202/500 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.643); catalogued as rs1275553299; called by muse, mutect2, varscan2
- CDKN1A | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 182/705 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.353); catalogued as rs753529000, COSV55191210; called by muse, mutect2, varscan2
- CFHR2 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 51/295 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.089); catalogued as COSV100804371, COSV66380555; called by muse, mutect2, varscan2
- CHD3 | c.1716C>G p.I572M | Missense Mutation (SNP) | VAF 88/247 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV57874856; called by muse, mutect2, varscan2
- CLCN7 | c.857G>T p.R286L | Missense Mutation (SNP) | VAF 179/478 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM034393, COSV104387173; called by muse, mutect2, varscan2
- CMYA5 | c.9670C>T p.P3224S | Missense Mutation (SNP) | VAF 274/560 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV71407361; called by muse, mutect2, varscan2
- COL6A6 | c.3371C>T p.A1124V | Missense Mutation (SNP) | VAF 257/638 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.061); catalogued as rs1313074481; called by muse, mutect2, varscan2
- COL8A1 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 176/475 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV99657186; called by muse, mutect2, varscan2
- CYP11B2 | c.587C>T p.T196I | Missense Mutation (SNP) | VAF 440/752 reads (59%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.821); catalogued as rs762371852; called by muse, mutect2
- CYP21A2 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 90/719 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs72552757, CM022200; called by muse, mutect2, varscan2
- DDC | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 262/492 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63564181; called by muse, mutect2, varscan2
- DDX4 | c.1111G>C p.V371L | Missense Mutation (SNP) | VAF 235/447 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.871); catalogued as COSV100737741; called by muse, mutect2, varscan2
- DGKK | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 167/605 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as rs373977703, COSV65708353; called by muse, mutect2, varscan2
- DIO3 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 156/425 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.175); catalogued as rs531771210; called by muse, varscan2
- DOCK7 | c.3331C>T p.P1111S (on ENST00000635253 / NM_001367561.1; = p.P1080S on NM_033407.3) | Missense Mutation (SNP) | VAF 122/322 reads (38%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.894); catalogued as COSV52023593; called by muse, mutect2, varscan2
- DPYD | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 97/267 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV60077071; called by muse, mutect2, varscan2
- DZIP1 | c.1783C>T p.R595* (on ENST00000347108; = p.R576* on NM_014934.5) | Nonsense Mutation (SNP) | VAF 127/356 reads (36%) | catalogued as rs756109756, COSV61263776; called by muse, mutect2, varscan2
- ECEL1 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 165/451 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs984190240; called by muse, mutect2, varscan2
- ENTHD1 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 119/330 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV57318219; called by muse, mutect2, varscan2
- EPHA3 | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 119/317 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs144998277; called by muse, mutect2, varscan2
- EXOC5 | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 112/318 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs868177967, COSV61770140; called by muse, mutect2, varscan2
- FAM47A | c.2194G>A p.D732N | Missense Mutation (SNP) | VAF 141/577 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs867405123, COSV60499777; called by muse, mutect2, varscan2
- FAT4 | c.6142C>T p.P2048S | Missense Mutation (SNP) | VAF 153/360 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.329); catalogued as rs1390853845; called by muse, mutect2, varscan2
- FBLN1 | c.2050G>A p.G684S | Missense Mutation (SNP) | VAF 164/472 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs781566348; called by muse, mutect2, varscan2
- FGA | c.2574G>A p.M858I | Missense Mutation (SNP) | VAF 114/329 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV57396117; called by muse, mutect2, varscan2
- FGD5 | c.2446G>A p.E816K | Missense Mutation (SNP) | VAF 162/447 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53241938; called by muse, mutect2, varscan2
- FSD1 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 145/317 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs772916715, COSV55696785; called by muse, mutect2, varscan2
- GRIN2A | c.3364G>A p.G1122S | Missense Mutation (SNP) | VAF 173/483 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58038884, COSV58055547; called by muse, mutect2, varscan2
- GRIN3A | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 139/474 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV100701527, COSV62458248; called by muse, mutect2
- GUCY2F | c.1315C>T p.H439Y | Missense Mutation (SNP) | VAF 199/320 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.296); catalogued as rs867112346, COSV54307615; called by muse, mutect2, varscan2
- HAS1 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 180/476 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200078680, COSV55787952; called by muse, mutect2, varscan2
- HLA-DQA1 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 208/662 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58237164; called by muse, mutect2
- HLA-DQA2 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 328/1440 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs267600977, COSV66564580; called by muse, mutect2
- HRNR | c.964C>T p.H322Y | Missense Mutation (SNP) | VAF 155/814 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1373683856, COSV64263074; called by muse, mutect2, varscan2
- HS1BP3 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 172/506 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as rs1056689766; called by muse, varscan2
- HTR3D | c.1096G>A p.G366R (on ENST00000382489 / NM_001163646.2; = p.G191R on NM_182537.3) | Missense Mutation (SNP) | VAF 151/455 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.152); catalogued as COSV61913809; called by muse, mutect2, varscan2
- HYDIN | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.306); catalogued as rs1466755582; called by muse, mutect2, varscan2
- IGHV7-81 | c.197G>A p.W66* | Nonsense Mutation (SNP) | VAF 95/301 reads (32%) | catalogued as rs267603904; called by muse, mutect2, varscan2
- IL23R | c.799G>A p.V267I | Missense Mutation (SNP) | VAF 80/213 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.12); catalogued as rs542279299; called by muse, mutect2, varscan2
- IL31RA | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 266/489 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs780214655; called by muse, mutect2, varscan2
- IL31RA | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 305/570 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0.041); catalogued as COSV61693817; called by muse, mutect2, varscan2
- ITGA2B | c.1951G>A p.G651S | Missense Mutation (SNP) | VAF 127/349 reads (36%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.519); catalogued as rs868075402, COSV52234829; called by muse, mutect2, varscan2
- ITM2A | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 183/479 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs778605712, COSV64811525; called by muse, mutect2, varscan2
- ITPR2 | c.7087C>T p.H2363Y | Missense Mutation (SNP) | VAF 105/269 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1378201976; called by muse, mutect2, varscan2
- KIF2B | c.1331C>T p.S444F | Missense Mutation (SNP) | VAF 122/373 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs149614209, COSV52129478; called by muse, mutect2, varscan2
- KIF3B | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 164/406 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100996354; called by muse, mutect2, varscan2
- KMT2D | c.11737C>T p.Q3913* | Nonsense Mutation (SNP) | VAF 265/713 reads (37%) | catalogued as COSV56433536; called by muse, mutect2, varscan2
- KPRP | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 223/1024 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as rs747399681; called by muse, mutect2, varscan2
- KRT17 | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 107/296 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV60862164; called by muse, mutect2, varscan2
- KRTAP29-1 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 258/688 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1249984744; called by muse, mutect2, varscan2
- LAMA2 | c.3052C>T p.H1018Y | Missense Mutation (SNP) | VAF 71/204 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.865); catalogued as rs760657456; called by muse, mutect2, varscan2
- LAMA5 | c.3550C>T p.L1184= | Splice Region (SNP) | VAF 79/252 reads (31%) | catalogued as COSV53367400; called by muse, mutect2, varscan2
- LAMB1 | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 114/460 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.742); catalogued as rs760662838; called by muse, mutect2, varscan2
- LIF | c.20G>C p.G7A | Missense Mutation (SNP) | VAF 105/288 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs748305575; called by muse, mutect2, varscan2
- LILRA2 | c.871G>A p.G291S | Missense Mutation (SNP) | VAF 255/761 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs780162689, COSV99252594; called by muse, mutect2, varscan2
- MAGEB1 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 362/659 reads (55%) | SIFT tolerated (0.88); PolyPhen benign (0.348); catalogued as rs201687675, COSV100974987; called by muse, mutect2, varscan2
- MAGEC1 | c.2570C>T p.S857F | Missense Mutation (SNP) | VAF 145/263 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99596743; called by muse, mutect2, varscan2
- MARCHF1 | c.292C>T p.R98C (on ENST00000274056; = p.R81C on NM_017923.4) | Missense Mutation (SNP) | VAF 146/415 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as rs774218235, COSV99920175; called by muse, mutect2, varscan2
- MCF2L | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 140/393 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV65100927; called by muse, mutect2, varscan2
- MED12 | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 148/390 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV61361123; called by muse, mutect2, varscan2
- MEFV | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 197/530 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs104895116, CM035568, COSV54824683; ClinVar: uncertain significance; called by muse, varscan2
- MPO | c.1531C>T p.R511C | Missense Mutation (SNP) | VAF 171/454 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780347527, COSV51862416; called by muse, mutect2, varscan2
- MUC16 | c.28373C>T p.S9458F | Missense Mutation (SNP) | VAF 151/388 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.186); catalogued as rs1313660878, COSV67479698, COSV67495432; called by muse, mutect2, varscan2
- MUC16 | c.12557C>T p.T4186I | Missense Mutation (SNP) | VAF 130/369 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.079); catalogued as rs748931446; called by muse, varscan2
- MUC4 | c.3508C>T p.P1170S | Missense Mutation (SNP) | VAF 90/326 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.935); catalogued as rs1304418588; called by muse, mutect2
- MYH14 | c.2098C>T p.H700Y | Missense Mutation (SNP) | VAF 148/306 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.399); catalogued as COSV51826782; called by muse, varscan2
- MYOM1 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 135/380 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1001422774, COSV99868820; called by muse, mutect2, varscan2
- NCAN | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 110/324 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs781419287; called by muse, mutect2, varscan2
- NCKAP5 | c.5573G>A p.G1858E | Missense Mutation (SNP) | VAF 113/334 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58474534; called by muse, mutect2, varscan2
- NLRP5 | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 65/232 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.033); catalogued as rs917070859, COSV101173728; called by muse, mutect2, varscan2
- NOS3 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 132/592 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369489094; called by muse, mutect2, varscan2
- NRSN1 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 179/711 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65894073; called by muse, mutect2, varscan2
- NT5C1B | c.752G>A p.G251E (on ENST00000359846 / NM_001199086.2; = p.G191E on NM_033253.4) | Missense Mutation (SNP) | VAF 188/519 reads (36%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.022); catalogued as COSV58397171; called by muse, mutect2, varscan2
- NTRK3 | c.2386C>T p.P796S (on ENST00000360948 / NM_001012338.2; = p.P782S on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 137/565 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62316168; called by muse, mutect2, varscan2
- NUP210L | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 64/319 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55142893; called by muse, mutect2, varscan2
- OR10A3 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 150/461 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs866622532, COSV62459092; called by muse, mutect2, varscan2
- OR11H2 | c.496C>T p.L166F (on ENST00000556246; = p.L177F on NM_001197287.1) | Missense Mutation (SNP) | VAF 196/647 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.03); catalogued as COSV73703642; called by muse, mutect2, varscan2
- OR1J2 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 186/523 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs1358852493, COSV100093477, COSV58943920; called by muse, mutect2, varscan2
- OR2T34 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 132/856 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as rs374287459, COSV100170210; called by muse, mutect2, varscan2
- OR4A47 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 132/386 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.015); catalogued as rs1468528217; called by muse, mutect2, varscan2
- OR4M1 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 149/392 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0.182); catalogued as COSV104411332; called by muse, mutect2, varscan2
- OR6S1 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 203/530 reads (38%) | catalogued as rs1390862722, COSV57838847; called by muse, mutect2
- OSBPL10 | c.1822G>A p.G608R | Missense Mutation (SNP) | VAF 179/469 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202179987, COSV67342798; called by muse, mutect2, varscan2
- OTOGL | c.5765G>A p.G1922D (on ENST00000547103; = p.G1913D on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 100/270 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV54017413; called by muse, mutect2, varscan2
- PAH | c.1259G>A p.R420K | Missense Mutation (SNP) | VAF 141/333 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as CM133115, COSV61016107; called by muse, mutect2, varscan2
- PCDH17 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 188/518 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV64972204; called by muse, mutect2, varscan2
- PKHD1L1 | c.3001-1G>A p.X1001_splice | Splice Site (SNP) | VAF 53/263 reads (20%) | catalogued as COSV65738549; called by muse, mutect2, varscan2
- POR | c.1372T>C p.Y458H | Missense Mutation (SNP) | VAF 151/556 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1467767754; called by muse, mutect2, varscan2
- PRAME | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 154/445 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.716); catalogued as rs781779983, COSV67161348; called by muse, mutect2, varscan2
- PROKR2 | c.908C>T p.T303I | Missense Mutation (SNP) | VAF 132/375 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.09); catalogued as COSV54086774; called by muse, mutect2, varscan2
- PSG1 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 72/370 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.931); catalogued as rs761604220, COSV54952162; called by muse, mutect2
- PSG8 | c.430C>T p.L144= | Splice Region (SNP) | VAF 53/158 reads (34%) | catalogued as rs1466865677, COSV60610769; called by muse, mutect2, varscan2
- PTPRU | c.1697C>T p.S566F | Missense Mutation (SNP) | VAF 190/485 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV60521907; called by muse, mutect2, varscan2
- PYGO1 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 196/715 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1389657573, COSV57346650; called by muse, mutect2, varscan2
- QPRT | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 227/612 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1165498778; called by muse, mutect2, varscan2
- RAB44 | c.2611C>T p.R871W | Missense Mutation (SNP) | VAF 98/401 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs866196312, COSV57713177; called by muse, mutect2, varscan2
- RIMS1 | c.857T>C p.L286P | Missense Mutation (SNP) | VAF 156/444 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs933622337; called by muse, mutect2, varscan2
- RNF180 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 252/357 reads (71%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs371172901; called by muse, mutect2, varscan2
- ROCK2 | c.3235C>T p.Q1079* | Nonsense Mutation (SNP) | VAF 101/289 reads (35%) | catalogued as COSV100255746; called by muse, mutect2, varscan2
- RYR2 | c.1865G>A p.G622E | Missense Mutation (SNP) | VAF 135/596 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV100773288, COSV63711919; called by muse, mutect2, varscan2
- SALL3 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 206/555 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV73306074; called by muse, mutect2, varscan2
- SALL4 | c.1985C>T p.P662L | Missense Mutation (SNP) | VAF 175/457 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.057); catalogued as COSV53854549; called by muse, mutect2, varscan2
- SATB1 | c.1955C>T p.S652L | Missense Mutation (SNP) | VAF 147/443 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58673404; called by muse, mutect2, varscan2
- SHANK3 | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 144/368 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as rs1314696433; called by muse, mutect2, varscan2
- SIM1 | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 177/444 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.015); catalogued as rs370920653; called by muse, mutect2, varscan2
- SLC13A1 | c.1124T>A p.L375H | Missense Mutation (SNP) | VAF 359/438 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1373519953; called by muse, mutect2, varscan2
- SLC15A2 | c.1820C>T p.S607F | Missense Mutation (SNP) | VAF 173/474 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as rs749399079; called by muse, mutect2, varscan2
- SLC22A3 | c.1412C>T p.S471L | Missense Mutation (SNP) | VAF 121/333 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.155); catalogued as rs757358060; called by muse, mutect2, varscan2
- SLIT2 | c.3220G>A p.D1074N | Missense Mutation (SNP) | VAF 137/364 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as rs143782841, COSV56582960; called by muse, mutect2, varscan2
- SPDEF | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 337/622 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.34); catalogued as rs750333156; called by muse, mutect2, varscan2
- SPEF2 | c.2942G>A p.G981E | Missense Mutation (SNP) | VAF 96/385 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.121); catalogued as rs866774074, COSV61543955; called by muse, mutect2, varscan2
- STK31 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 327/606 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV63455221, COSV63455571; called by muse, mutect2, varscan2
- SVEP1 | c.1796A>G p.E599G | Missense Mutation (SNP) | VAF 87/228 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as rs1280167610; called by muse, mutect2, varscan2
- TAF1L | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 187/528 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99644076; called by muse, mutect2, varscan2
- TDRD6 | c.3394G>A p.D1132N | Missense Mutation (SNP) | VAF 107/267 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as rs772857539, COSV100288166; called by muse, mutect2, varscan2
- TDRKH | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 114/568 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs140584958; called by muse, mutect2, varscan2
- TEX44 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 170/422 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs141442188; called by muse, mutect2, varscan2
- TMEM232 | c.1958G>A p.R653K | Missense Mutation (SNP) | VAF 75/184 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV70270512; called by muse, mutect2, varscan2
- TNS3 | c.2876C>T p.S959F | Missense Mutation (SNP) | VAF 388/724 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs754925928, COSV100236042; called by muse, mutect2, varscan2
- TNXB | c.8578G>A p.E2860K (on ENST00000647633; = p.E2613K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 168/583 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.348); catalogued as rs750359249; called by muse, mutect2, varscan2
- TPST2 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 159/476 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757363608, COSV100114212; called by muse, mutect2, varscan2
- TRPM8 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 179/523 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV61220329; called by muse, mutect2, varscan2
- TTLL4 | c.1604C>T p.S535L | Missense Mutation (SNP) | VAF 130/328 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as rs1319949085; called by muse, mutect2, varscan2
- UGT1A7 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 192/453 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60830276; called by muse, mutect2, varscan2
- UNC13D | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 119/318 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1292403747, COSV52884613; called by muse, mutect2, varscan2
- VCX3A | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 92/1270 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs775347459; called by muse, mutect2
- VSTM2L | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 184/563 reads (33%) | catalogued as COSV65096331; called by muse, mutect2, varscan2
- WASL | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 65/103 reads (63%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs373888010; called by muse, mutect2, varscan2
- XIRP2 | c.8881C>T p.P2961S (on ENST00000628543; = p.P3136S on NM_152381.6) | Missense Mutation (SNP) | VAF 124/385 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as rs1204907454; called by muse, mutect2, varscan2
- ZAN | c.2773G>A p.E925K | Missense Mutation (SNP) | VAF 209/890 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as rs1424615172; called by muse, mutect2, varscan2
- ZC3H6 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 161/473 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs1261330756; called by muse, mutect2, varscan2
- ZDHHC15 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 116/357 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs761758054; called by muse, mutect2, varscan2
- ZFP92 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 242/389 reads (62%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.739); catalogued as rs1556975026; called by muse, mutect2, varscan2
- ZNF208 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 98/279 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV68100587; called by muse, mutect2, varscan2
- ZNF431 | c.1571C>T p.S524F | Missense Mutation (SNP) | VAF 127/358 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs770133905; called by muse, mutect2, varscan2
- ZNF536 | c.3556G>A p.E1186K | Missense Mutation (SNP) | VAF 181/514 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.709); catalogued as rs543048949, COSV62821117; called by muse, mutect2, varscan2
- ZNF611 | c.1988C>T p.S663L | Missense Mutation (SNP) | VAF 130/381 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); catalogued as COSV60542768; called by muse, mutect2, varscan2
- ZNF674 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 160/416 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as rs368179569, COSV70379283; called by muse, mutect2, varscan2
- ZP2 | c.1196G>A p.G399E | Missense Mutation (SNP) | VAF 158/407 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs1329506494, COSV54812534; called by muse, mutect2, varscan2
- ADCY9 | c.2285C>T p.S762F | Missense Mutation (SNP) | VAF 122/343 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ADGRA3 | c.2869G>A p.E957K | Missense Mutation (SNP) | VAF 159/458 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- ADGRF5 | c.2312G>A p.G771E | Missense Mutation (SNP) | VAF 129/397 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- ADH1C | c.401G>A p.S134N | Missense Mutation (SNP) | VAF 168/434 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADRA2A | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 186/290 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- AHNAK | c.4569del p.F1523Lfs*10 | Frame Shift Del (DEL) | VAF 197/573 reads (34%) | called by mutect2, pindel, varscan2
- AK9 | c.2758G>A p.D920N | Missense Mutation (SNP) | VAF 83/213 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- AKAP4 | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 206/764 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGAP15 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 104/319 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARVCF | c.2774C>T p.P925L | Missense Mutation (SNP) | VAF 145/350 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2
- ASXL3 | c.1281A>T p.E427D | Missense Mutation (SNP) | VAF 154/407 reads (38%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATXN1L | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 180/577 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- BAHCC1 | c.2437C>T p.P813S | Missense Mutation (SNP) | VAF 220/501 reads (44%) | SIFT tolerated (0.97); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- BTNL2 | c.503G>A p.G168D | Missense Mutation (SNP) | VAF 204/701 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1orf146 | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); called by muse, varscan2
- C3orf56 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 153/418 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- C7orf50 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 108/383 reads (28%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- CARF | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 71/220 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- CCDC88C | c.4916G>A p.G1639E | Missense Mutation (SNP) | VAF 197/545 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- CDHR1 | c.2092C>T p.P698S | Missense Mutation (SNP) | VAF 124/204 reads (61%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHAC1 | c.368C>T p.T123I | Missense Mutation (SNP) | VAF 369/675 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- CLK1 | c.283A>C p.S95R | Missense Mutation (SNP) | VAF 153/447 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- COL11A2 | c.1291C>T p.P431S (on ENST00000341947 / NM_080680.3; = p.P324S on NM_080679.2) | Missense Mutation (SNP) | VAF 181/755 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A4 | c.1489G>A p.G497R | Missense Mutation (SNP) | VAF 143/373 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- CRISP3 | c.71C>T p.S24F (on ENST00000371159 / NM_001368123.1; = p.S16F on NM_001190986.2) | Missense Mutation (SNP) | VAF 178/494 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- CRYBB2 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 150/418 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTTN | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 258/351 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- CTTNBP2 | c.1619G>A p.G540E | Missense Mutation (SNP) | VAF 531/619 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYLC1 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 153/224 reads (68%) | SIFT tolerated (0.16); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- CYP2C9 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 131/195 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- CYP8B1 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 156/440 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- DCAF8L2 | c.1103G>A p.G368E | Missense Mutation (SNP) | VAF 353/607 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DLEC1 | c.3007C>T p.H1003Y | Missense Mutation (SNP) | VAF 82/224 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOCK3 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 131/402 reads (33%) | called by muse, mutect2, varscan2
- DOCK9 | c.1403C>T p.P468L (on ENST00000376460 / NM_001366676.2; = p.P469L on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/269 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DYRK3 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 158/731 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- EFCAB5 | c.909G>A p.M303I | Missense Mutation (SNP) | VAF 86/249 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EFCAB8 | c.2333C>T p.S778F | Missense Mutation (SNP) | VAF 139/412 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- EHBP1L1 | c.4176G>A p.M1392I | Missense Mutation (SNP) | VAF 221/317 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ELOA3B | c.873G>A p.M291I | Missense Mutation (SNP) | VAF 169/3561 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.167); called by muse, mutect2
- EPHA6 | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 124/356 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- EPN3 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 153/416 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FAM107A | c.239T>C p.I80T | Missense Mutation (SNP) | VAF 219/565 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- FANCE | c.1105C>T p.L369F | Missense Mutation (SNP) | VAF 92/368 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXW7 | c.1001T>A p.L334* (on ENST00000281708 / NM_001349798.2; = p.L254* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 101/246 reads (41%) | called by muse, varscan2
- FLYWCH2 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 253/720 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- GIMAP4 | c.901G>C p.V301L | Missense Mutation (SNP) | VAF 378/476 reads (79%) | SIFT deleterious (0.04); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- GOLGA6B | c.1811T>G p.L604R | Missense Mutation (SNP) | VAF 65/727 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HMBOX1 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 104/466 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- HMCN1 | c.8191C>T p.Q2731* | Nonsense Mutation (SNP) | VAF 165/763 reads (22%) | called by muse, mutect2, varscan2
- IFT88 | c.1012C>T p.Q338* (on ENST00000319980 / NM_001318493.2; = p.Q329* on NM_006531.5 and 9 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 88/254 reads (35%) | called by muse, mutect2, varscan2
- IGF2BP1 | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 104/283 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- IQCC | c.1033C>T p.L345F | Missense Mutation (SNP) | VAF 131/373 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- IRS4 | c.1445G>A p.G482E | Missense Mutation (SNP) | VAF 251/390 reads (64%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ITGB3 | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 147/409 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITIH4 | c.2194C>T p.P732S | Missense Mutation (SNP) | VAF 154/394 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- JPH1 | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 319/478 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KIF13A | c.9T>A p.D3E | Missense Mutation (SNP) | VAF 198/414 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- KIR2DL4 | c.364C>T p.L122F (on ENST00000396284; = p.L83F on NM_001080770.2) | Missense Mutation (SNP) | VAF 94/232 reads (41%) | SIFT tolerated (0.75); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- LIG3 | c.1600C>T p.L534F | Missense Mutation (SNP) | VAF 110/337 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LMTK3 | c.2211G>A p.M737I | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRC43 | c.1505C>A p.P502H | Missense Mutation (SNP) | VAF 87/249 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- LRRC6 | c.359T>G p.L120R | Missense Mutation (SNP) | VAF 136/714 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAP3K10 | c.1990G>A p.G664R | Missense Mutation (SNP) | VAF 128/348 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MAPRE2 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 121/343 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MARCO | c.1183C>T p.Q395* | Nonsense Mutation (SNP) | VAF 121/362 reads (33%) | called by muse, mutect2, varscan2
- MBTPS1 | c.1849C>T p.P617S | Missense Mutation (SNP) | VAF 177/482 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MDFIC2 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 166/410 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- ME3 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 275/385 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MIA2 | c.1403G>A p.W468* | Nonsense Mutation (SNP) | VAF 89/266 reads (33%) | called by muse, mutect2, varscan2
- MIA2 | c.469T>G p.S157A | Missense Mutation (SNP) | VAF 81/202 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MRGPRX2 | c.149T>C p.F50S | Missense Mutation (SNP) | VAF 166/475 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MUC16 | c.40536G>T p.Q13512H | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- MUC4 | c.10799C>T p.P3600L | Missense Mutation (SNP) | VAF 90/926 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.722); called by muse, varscan2
- MUC4 | c.4132C>T p.P1378S | Missense Mutation (SNP) | VAF 89/330 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.65); called by muse, mutect2
- MYH1 | c.5465G>A p.R1822K | Missense Mutation (SNP) | VAF 126/292 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.074); called by muse, varscan2
- MYH11 | c.3412G>A p.E1138K | Missense Mutation (SNP) | VAF 214/572 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MYLK | c.3261T>A p.N1087K | Missense Mutation (SNP) | VAF 209/503 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYO7B | c.4849G>A p.E1617K | Missense Mutation (SNP) | VAF 87/237 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NLRP6 | c.2614G>A p.V872I | Missense Mutation (SNP) | VAF 187/509 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- NXPE4 | c.1408G>A p.V470I (on ENST00000375478 / NM_001077639.2; = p.V186I on NM_017678.3) | Missense Mutation (SNP) | VAF 316/409 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OPA3 | c.23T>C p.M8T | Missense Mutation (SNP) | VAF 142/406 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- OR51B2 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 140/389 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- OR5D13 | c.282C>G p.I94M | Missense Mutation (SNP) | VAF 150/409 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- PAMR1 | c.973G>A p.E325K (on ENST00000619888 / NM_001001991.3; = p.E342K on NM_015430.4) | Missense Mutation (SNP) | VAF 152/414 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- PARD3B | c.1255G>A p.G419R | Missense Mutation (SNP) | VAF 113/360 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PARD6A | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 221/597 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCLO | c.5380G>A p.E1794K | Missense Mutation (SNP) | VAF 109/501 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PDE1C | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 220/415 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PIEZO2 | c.5371G>A p.E1791K | Missense Mutation (SNP) | VAF 187/521 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PIK3R4 | c.3238C>T p.P1080S | Missense Mutation (SNP) | VAF 99/250 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PLEKHO1 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 161/734 reads (22%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLXNB2 | c.1957C>T p.P653S | Missense Mutation (SNP) | VAF 184/498 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- POMC | c.218A>G p.N73S | Missense Mutation (SNP) | VAF 229/589 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- POMT2 | c.1785+1G>T p.X595_splice | Splice Site (SNP) | VAF 122/310 reads (39%) | called by muse, mutect2, varscan2
- PRELP | c.658C>T p.L220F | Missense Mutation (SNP) | VAF 177/870 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRR36 | c.2702C>T p.P901L | Missense Mutation (SNP) | VAF 110/266 reads (41%) | SIFT tolerated (0.29); called by muse, mutect2, varscan2
- REC114 | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 144/541 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ROCK1 | c.2489+1G>A p.X830_splice | Splice Site (SNP) | VAF 52/128 reads (41%) | called by muse, mutect2, varscan2
- RPGRIP1 | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 101/256 reads (39%) | called by muse, mutect2, varscan2
- RXFP2 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 119/333 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SATB1 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 141/406 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCAF4 | c.2203C>T p.P735S | Missense Mutation (SNP) | VAF 116/340 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SF1 | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 194/518 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- SH3RF2 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 248/313 reads (79%) | SIFT tolerated (0.06); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- SLBP | c.484C>T p.L162F | Missense Mutation (SNP) | VAF 89/239 reads (37%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SLC22A7 | c.1156G>A p.E386K (on ENST00000372585 / NM_153320.2; = p.E384K on NM_006672.3) | Missense Mutation (SNP) | VAF 177/635 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC44A4 | c.859G>A p.G287S | Missense Mutation (SNP) | VAF 202/786 reads (26%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- SNX29 | c.2179G>A p.D727N | Missense Mutation (SNP) | VAF 85/233 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- SORBS2 | c.1400C>T p.S467F | Missense Mutation (SNP) | VAF 167/426 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SPARCL1 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 131/399 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2
- SSBP2 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 70/306 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- STAG1 | c.1101G>T p.L367F | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- STAG1 | c.1100T>A p.L367* | Nonsense Mutation (SNP) | VAF 67/172 reads (39%) | called by muse, mutect2, varscan2
- SYCP2L | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 109/472 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAF1A | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 227/349 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBX2 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 145/389 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- TENM3 | c.2507C>T p.S836F | Missense Mutation (SNP) | VAF 148/409 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- TEX15 | c.11A>T p.K4I | Missense Mutation (SNP) | VAF 288/430 reads (67%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- TIAM2 | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 150/364 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- TLR2 | c.712C>T p.H238Y | Missense Mutation (SNP) | VAF 108/267 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM160 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 240/647 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TOGARAM2 | c.2289G>A p.M763I | Missense Mutation (SNP) | VAF 231/622 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TOX3 | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 178/465 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TRIM49B | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 169/426 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TSEN15 | c.487C>T p.Q163* (on ENST00000645963; = p.A137= on NM_001363643.2) | Nonsense Mutation (SNP) | VAF 123/658 reads (19%) | called by muse, mutect2, varscan2
- TTN | c.58217G>A p.G19406E (on ENST00000591111; = p.G11982E on NM_003319.4) | Missense Mutation (SNP) | VAF 152/421 reads (36%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.39771T>A p.Y13257* (on ENST00000591111; = p.Y5833* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 203/482 reads (42%) | called by muse, mutect2, varscan2
- TTN | c.314A>G p.N105S | Missense Mutation (SNP) | VAF 109/272 reads (40%) | PolyPhen benign (0.116); called by muse, mutect2, varscan2
- TXNRD3 | c.866A>G p.K289R | Missense Mutation (SNP) | VAF 100/280 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UBTF | c.112C>T p.L38F | Missense Mutation (SNP) | VAF 181/523 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UMODL1 | c.1296C>G p.H432Q | Missense Mutation (SNP) | VAF 59/189 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- UMODL1 | c.1730G>A p.G577E | Missense Mutation (SNP) | VAF 165/495 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- USF3 | c.4997C>T p.S1666L | Missense Mutation (SNP) | VAF 126/396 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USF3 | c.3106C>T p.P1036S | Missense Mutation (SNP) | VAF 124/315 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- VIPR1 | c.858G>A p.W286* | Nonsense Mutation (SNP) | VAF 133/377 reads (35%) | called by muse, mutect2, varscan2
- ZBTB22 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 286/1048 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZC3H3 | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 236/1069 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZFHX4 | c.7249G>A p.D2417N | Missense Mutation (SNP) | VAF 504/821 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- ZFPM2 | c.2998C>T p.H1000Y | Missense Mutation (SNP) | VAF 121/541 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF235 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 116/319 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF287 | c.1747C>G p.Q583E | Missense Mutation (SNP) | VAF 165/421 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF41 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 217/425 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF410 | c.848A>G p.E283G | Missense Mutation (SNP) | VAF 172/478 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF469 | c.5068C>T p.Q1690* (on ENST00000437464; = p.Q1718* on NM_001367624.2) | Nonsense Mutation (SNP) | VAF 160/444 reads (36%) | called by muse, varscan2
- ABCA9 | c.1311C>T p.F437= | Silent (SNP) | VAF 105/300 reads (35%) | catalogued as rs542953429; called by muse, mutect2, varscan2
- AC004593.2 | c.1488C>T p.F496= | Silent (SNP) | VAF 127/432 reads (29%) | called by muse, mutect2, varscan2
- ADGB | c.4824C>T p.S1608= | Silent (SNP) | VAF 54/144 reads (38%) | called by muse, varscan2
- ADGB | c.4995G>A p.K1665= | Silent (SNP) | VAF 40/147 reads (27%) | called by muse, varscan2
- AHNAK | c.17052C>T p.F5684= | Silent (SNP) | VAF 111/315 reads (35%) | called by muse, mutect2, varscan2
- AKR7A3 | c.582C>T p.F194= | Silent (SNP) | VAF 153/428 reads (36%) | called by muse, mutect2, varscan2
- ALLC | c.129G>A p.G43= | Silent (SNP) | VAF 140/383 reads (37%) | catalogued as COSV52998680; called by muse, mutect2, varscan2
- AMER1 | c.1065G>A p.G355= | Silent (SNP) | VAF 246/671 reads (37%) | catalogued as rs765423200, COSV57666634; called by muse, mutect2, varscan2
- APOB | c.10254G>A p.T3418= | Silent (SNP) | VAF 144/402 reads (36%) | catalogued as rs781639766, COSV51928882; called by muse, mutect2, varscan2
- APOD | c.192C>T p.A64= | Silent (SNP) | VAF 138/339 reads (41%) | called by muse, mutect2, varscan2
- ARHGAP4 | c.1101C>T p.S367= | Silent (SNP) | VAF 147/272 reads (54%) | called by muse, mutect2, varscan2
- ATP6V1E2 | c.211C>T p.L71= | Silent (SNP) | VAF 133/370 reads (36%) | catalogued as rs146275885, COSV60576806; called by muse, mutect2, varscan2
- ATP7A | c.3720C>T p.I1240= | Silent (SNP) | VAF 172/437 reads (39%) | catalogued as COSV58454491; called by muse, mutect2, varscan2
- BMPER | c.240G>A p.K80= | Silent (SNP) | VAF 135/498 reads (27%) | catalogued as rs775250760, COSV51814997; called by muse, mutect2, varscan2
- C19orf84 | c.189C>T p.T63= | Silent (SNP) | VAF 249/697 reads (36%) | called by muse, mutect2, varscan2
- CAMK4 | c.255C>T p.I85= | Silent (SNP) | VAF 188/264 reads (71%) | catalogued as rs201866448, COSV56662707; called by muse, mutect2, varscan2
- CCL20 | c.264C>T p.L88= | Silent (SNP) | VAF 85/264 reads (32%) | called by muse, mutect2, varscan2
- CD33 | c.861G>A p.R287= | Silent (SNP) | VAF 156/420 reads (37%) | catalogued as rs750324224, COSV51804205; called by muse, mutect2
- CDKL5 | c.3012G>A p.R1004= | Silent (SNP) | VAF 322/583 reads (55%) | called by muse, mutect2, varscan2
- CFAP100 | c.696C>T p.I232= | Silent (SNP) | VAF 115/310 reads (37%) | called by muse, mutect2, varscan2
- CGB7 | c.267C>T p.L89= | Silent (SNP) | VAF 76/638 reads (12%) | called by muse, mutect2
- CHRNA2 | c.57C>T p.L19= | Silent (SNP) | VAF 127/561 reads (23%) | catalogued as COSV53558459; called by muse, mutect2, varscan2
- CLCN5 | c.1947G>A p.K649= | Silent (SNP) | VAF 218/433 reads (50%) | called by muse, mutect2, varscan2
- CNGA2 | c.1101C>T p.I367= | Silent (SNP) | VAF 204/321 reads (64%) | catalogued as rs141471697, COSV61704820; called by muse, mutect2, varscan2
- COL11A2 | c.1290C>T p.P430= (on ENST00000341947 / NM_080680.3; = p.P323= on NM_080679.2) | Silent (SNP) | VAF 171/746 reads (23%) | called by muse, mutect2, varscan2
- COL11A2 | c.699G>A p.R233= | Silent (SNP) | VAF 275/1036 reads (27%) | called by muse, mutect2, varscan2
- COL4A5 | c.1374C>T p.P458= | Silent (SNP) | VAF 118/189 reads (62%) | catalogued as COSV60374649; called by muse, mutect2, varscan2
- CRYBG2 | c.1431G>A p.R477= | Silent (SNP) | VAF 183/576 reads (32%) | called by muse, mutect2, varscan2
- CTTN | c.75C>T p.D25= | Silent (SNP) | VAF 254/348 reads (73%) | catalogued as rs780456539; called by muse, varscan2
- CYP2C8 | c.1065C>T p.I355= | Silent (SNP) | VAF 141/209 reads (67%) | called by muse, mutect2, varscan2
- DCAF4L2 | c.1098G>A p.V366= | Silent (SNP) | VAF 163/739 reads (22%) | catalogued as COSV100151287, COSV60476751; called by muse, mutect2, varscan2
- DCX | c.420G>A p.K140= | Silent (SNP) | VAF 179/299 reads (60%) | called by muse, mutect2, varscan2
- DGKG | c.990G>A p.R330= | Silent (SNP) | VAF 111/270 reads (41%) | called by muse, mutect2, varscan2
- DNAH11 | c.9315G>A p.K3105= | Silent (SNP) | VAF 106/382 reads (28%) | called by muse, mutect2, varscan2
- DNAH9 | c.2178C>T p.F726= | Silent (SNP) | VAF 179/538 reads (33%) | called by muse, mutect2, varscan2
- DOCK4 | c.4068C>T p.F1356= | Silent (SNP) | VAF 184/642 reads (29%) | catalogued as COSV101445628; called by muse, mutect2, varscan2
- DOP1B | c.1773C>T p.I591= | Silent (SNP) | VAF 166/471 reads (35%) | catalogued as rs141312847; called by muse, mutect2, varscan2
- DROSHA | c.3498C>T p.F1166= | Silent (SNP) | VAF 101/416 reads (24%) | called by muse, mutect2, varscan2
- EBF2 | c.807C>T p.A269= | Silent (SNP) | VAF 147/748 reads (20%) | catalogued as rs1340555058, COSV68779962; called by muse, mutect2, varscan2
- EML4 | c.756G>A p.T252= | Silent (SNP) | VAF 108/304 reads (36%) | catalogued as rs370639523, COSV100580692; called by muse, mutect2, varscan2
- EPDR1 | c.615C>T p.T205= | Silent (SNP) | VAF 152/508 reads (30%) | called by muse, mutect2, varscan2
- EPHA8 | c.258G>A p.T86= | Silent (SNP) | VAF 125/419 reads (30%) | catalogued as rs774681506, COSV51264404; called by muse, mutect2, varscan2
- EPN3 | c.930C>T p.A310= | Silent (SNP) | VAF 154/418 reads (37%) | catalogued as rs760143622; called by muse, mutect2, varscan2
- ERBB4 | c.1026G>A p.L342= | Silent (SNP) | VAF 88/242 reads (36%) | catalogued as rs149272231, COSV99632326; called by muse, mutect2, varscan2
- FADS3 | c.427C>T p.L143= | Silent (SNP) | VAF 240/615 reads (39%) | called by muse, mutect2, varscan2
- FAM131C | c.810C>T p.S270= | Silent (SNP) | VAF 153/548 reads (28%) | catalogued as rs1486897484; called by muse, mutect2, varscan2
- FAM171A2 | c.843C>T p.F281= | Silent (SNP) | VAF 143/405 reads (35%) | catalogued as rs1366976436; called by muse, mutect2, varscan2
- FAM3D | c.642G>A p.E214= | Silent (SNP) | VAF 159/431 reads (37%) | catalogued as rs747546214; called by muse, mutect2, varscan2
- FASTKD1 | c.1170C>T p.F390= | Silent (SNP) | VAF 57/196 reads (29%) | called by muse, mutect2, varscan2
- FBLN1 | c.2049G>A p.G683= | Silent (SNP) | VAF 164/472 reads (35%) | catalogued as COSV59940053; called by muse, mutect2, varscan2
- FIBIN | c.444G>A p.Q148= | Silent (SNP) | VAF 173/455 reads (38%) | catalogued as rs181248433, COSV100590467; called by muse, mutect2, varscan2
- FLG2 | c.5382G>A p.R1794= | Silent (SNP) | VAF 479/734 reads (65%) | catalogued as rs373836847; called by muse, mutect2, varscan2
- GABRA1 | c.519C>T p.F173= | Silent (SNP) | VAF 259/365 reads (71%) | catalogued as rs1276849167, COSV50099084; called by muse, mutect2, varscan2
- GBP1 | c.948C>T p.V316= | Silent (SNP) | VAF 173/503 reads (34%) | called by muse, mutect2, varscan2
- GIMAP2 | c.639C>T p.H213= | Silent (SNP) | VAF 488/584 reads (84%) | catalogued as rs149013037, COSV56234697; called by muse, mutect2, varscan2
- GRAMD1C | c.1119A>G p.E373= | Silent (SNP) | VAF 117/337 reads (35%) | called by muse, mutect2, varscan2
- GSPT2 | c.204C>T p.F68= | Silent (SNP) | VAF 213/588 reads (36%) | catalogued as COSV100468265; called by muse, varscan2
- HDAC9 | c.1956C>T p.T652= | Silent (SNP) | VAF 172/611 reads (28%) | called by muse, mutect2, varscan2
- HK3 | c.468G>A p.V156= | Silent (SNP) | VAF 118/463 reads (25%) | called by muse, mutect2, varscan2
- HMGCS2 | c.1515G>A p.R505= | Silent (SNP) | VAF 92/308 reads (30%) | called by muse, mutect2, varscan2
- HR | c.594C>T p.A198= | Silent (SNP) | VAF 362/625 reads (58%) | called by muse, mutect2, varscan2
- IER2 | c.648C>T p.L216= | Silent (SNP) | VAF 123/389 reads (32%) | called by muse, mutect2, varscan2
- IGHA1 | c.774G>A p.K258= | Silent (SNP) | VAF 70/585 reads (12%) | catalogued as rs1321708905; called by muse, mutect2, varscan2
- IGHA2 | c.735G>A p.K245= | Silent (SNP) | VAF 139/599 reads (23%) | catalogued as rs376379708; called by muse, mutect2, varscan2
- IGHV6-1 | c.55C>T p.L19= | Silent (SNP) | VAF 122/292 reads (42%) | called by muse, mutect2, varscan2
- IL1RAP | c.993C>T p.V331= | Silent (SNP) | VAF 133/408 reads (33%) | catalogued as rs1444312879; called by muse, mutect2, varscan2
- IL31RA | c.786G>A p.L262= | Silent (SNP) | VAF 265/486 reads (55%) | called by muse, mutect2, varscan2
- INF2 | c.1581C>T p.S527= | Silent (SNP) | VAF 196/541 reads (36%) | catalogued as rs928182488; called by muse, mutect2, varscan2
- KCNC4 | c.1053C>T p.F351= | Silent (SNP) | VAF 163/514 reads (32%) | catalogued as rs757033659, COSV63926357; called by muse, mutect2, varscan2
- KDELR1 | c.474C>T p.Y158= | Silent (SNP) | VAF 216/598 reads (36%) | called by muse, varscan2
- KDM6A | c.3615T>C p.V1205= | Silent (SNP) | VAF 315/624 reads (50%) | called by muse, mutect2, varscan2
- KDM6B | c.2223C>T p.A741= | Silent (SNP) | VAF 303/730 reads (42%) | catalogued as COSV54683880; called by muse, varscan2
- KIAA1191 | c.807C>T p.A269= | Silent (SNP) | VAF 184/650 reads (28%) | called by muse, mutect2, varscan2
- KIF17 | c.549C>T p.A183= | Silent (SNP) | VAF 178/538 reads (33%) | called by muse, mutect2, varscan2
- KRT37 | c.474C>T p.I158= | Silent (SNP) | VAF 126/375 reads (34%) | catalogued as rs148245015; called by muse, mutect2, varscan2
- LAMA3 | c.1497C>T p.L499= | Silent (SNP) | VAF 134/402 reads (33%) | catalogued as rs746080572, COSV58069278; called by muse, mutect2, varscan2
- LDB2 | c.780G>A p.R260= | Silent (SNP) | VAF 146/388 reads (38%) | catalogued as COSV58767498; called by muse, mutect2, varscan2
- MED10 | c.45C>T p.F15= | Silent (SNP) | VAF 254/465 reads (55%) | catalogued as COSV55386384; called by muse, mutect2, varscan2
- MEF2B | c.1074C>T p.A358= | Silent (SNP) | VAF 227/583 reads (39%) | catalogued as rs1376553706; called by muse, mutect2, varscan2
- MIB2 | c.2610C>T p.F870= | Silent (SNP) | VAF 186/553 reads (34%) | catalogued as rs772469204; called by muse, mutect2, varscan2
- MRGPRX1 | c.490C>T p.L164= | Silent (SNP) | VAF 155/421 reads (37%) | catalogued as COSV57110112; called by muse, mutect2, varscan2
- MUC16 | c.12750G>A p.T4250= | Silent (SNP) | VAF 150/429 reads (35%) | catalogued as rs918205385, COSV67470997; called by muse, mutect2, varscan2
- MUC16 | c.12447C>T p.S4149= | Silent (SNP) | VAF 178/422 reads (42%) | catalogued as rs1334968871; called by muse, varscan2
- MUC22 | c.3315C>T p.T1105= | Silent (SNP) | VAF 270/1053 reads (26%) | called by muse, varscan2
- MUC4 | c.6285C>T p.T2095= | Silent (SNP) | VAF 258/1928 reads (13%) | called by muse, mutect2
- MYO18B | c.330G>A p.E110= | Silent (SNP) | VAF 147/435 reads (34%) | catalogued as rs1042369636; called by muse, mutect2, varscan2
- MYO1F | c.285G>A p.R95= | Silent (SNP) | VAF 134/463 reads (29%) | catalogued as rs749028387; called by muse, mutect2
- MYO5A | c.5010C>T p.S1670= | Silent (SNP) | VAF 382/725 reads (53%) | catalogued as rs1275983902; called by muse, mutect2, varscan2
- MYPN | c.3306G>A p.P1102= | Silent (SNP) | VAF 109/193 reads (56%) | catalogued as rs771521427, COSV62741449; called by muse, mutect2, varscan2
- NLRP2 | c.1362C>T p.A454= | Silent (SNP) | VAF 264/707 reads (37%) | catalogued as rs369187273; called by muse, mutect2, varscan2
- NLRX1 | c.2178C>T p.A726= | Silent (SNP) | VAF 399/529 reads (75%) | called by muse, mutect2, varscan2
- NOS1 | c.801G>A p.G267= | Silent (SNP) | VAF 159/406 reads (39%) | catalogued as rs550005340; called by muse, mutect2, varscan2
- NPAS2 | c.1590C>T p.I530= | Silent (SNP) | VAF 121/360 reads (34%) | called by muse, mutect2, varscan2
- NUP210 | c.3549C>T p.T1183= | Silent (SNP) | VAF 142/422 reads (34%) | catalogued as rs946842347; called by muse, mutect2
- NUP42 | c.165C>A p.S55= | Silent (SNP) | VAF 124/508 reads (24%) | catalogued as rs768382123; called by muse, mutect2, varscan2
- NYAP2 | c.1059C>T p.S353= | Silent (SNP) | VAF 128/345 reads (37%) | called by muse, mutect2, varscan2
- OR2V1 | c.867C>T p.L289= | Silent (SNP) | VAF 168/615 reads (27%) | catalogued as COSV61458739; called by muse, mutect2, varscan2
- OR4C15 | c.342C>T p.F114= (on ENST00000314644; = p.F60= on NM_001001920.2) | Silent (SNP) | VAF 147/424 reads (35%) | catalogued as COSV100115384, COSV58953348; called by muse, mutect2, varscan2
- OR4C5 | c.201G>T p.V67= | Silent (SNP) | VAF 129/313 reads (41%) | catalogued as rs1232166695; called by muse, mutect2, varscan2
- OR51B4 | c.828C>T p.V276= | Silent (SNP) | VAF 118/379 reads (31%) | catalogued as rs201738028; called by muse, mutect2, varscan2
- OR51Q1 | c.864G>A p.V288= | Silent (SNP) | VAF 107/308 reads (35%) | catalogued as COSV56179254; called by muse, mutect2, varscan2
- OR5T1 | c.915G>A p.R305= | Silent (SNP) | VAF 124/338 reads (37%) | called by muse, mutect2, varscan2
- OR6J1 | c.918G>A p.R306= | Silent (SNP) | VAF 118/373 reads (32%) | called by muse, mutect2, varscan2
- OR9K2 | c.291C>T p.F97= (on ENST00000305377; = p.F75= on NM_001005243.1) | Silent (SNP) | VAF 173/445 reads (39%) | catalogued as COSV59532790; called by muse, mutect2, varscan2
- OTC | c.471C>T p.I157= | Silent (SNP) | VAF 380/673 reads (56%) | catalogued as COSV50004127; called by muse, mutect2, varscan2
- PCDHB11 | c.2124C>T p.F708= | Silent (SNP) | VAF 549/728 reads (75%) | catalogued as COSV61310554; called by muse, mutect2, varscan2
- PDGFC | c.76C>T p.L26= | Silent (SNP) | VAF 140/378 reads (37%) | called by muse, mutect2, varscan2
- PEG3 | c.1233C>T p.P411= | Silent (SNP) | VAF 105/295 reads (36%) | catalogued as rs778919349, COSV55634999, COSV99686585; called by muse, mutect2, varscan2
- PGK2 | c.837G>A p.R279= | Silent (SNP) | VAF 142/424 reads (33%) | catalogued as rs1052199909; called by muse, mutect2, varscan2
- PHLDB2 | c.2535G>A p.T845= (on ENST00000393925 / NM_001134439.2; = p.T802= on NM_145753.2) | Silent (SNP) | VAF 104/298 reads (35%) | catalogued as rs914440015, COSV67308373; called by muse, mutect2, varscan2
- PID1 | c.114C>T p.F38= | Silent (SNP) | VAF 125/294 reads (43%) | called by muse, mutect2, varscan2
- PIK3C2G | c.2577C>T p.F859= (on ENST00000676171; = p.F818= on NM_004570.5) | Silent (SNP) | VAF 154/400 reads (39%) | catalogued as COSV99849478; called by muse, mutect2, varscan2
- PLA2G2E | c.156C>T p.H52= | Silent (SNP) | VAF 135/365 reads (37%) | catalogued as rs900201752; called by muse, mutect2, varscan2
- POM121L12 | c.594C>T p.F198= | Silent (SNP) | VAF 189/672 reads (28%) | catalogued as rs1398358196, COSV68692268; called by muse, varscan2
- PPID | c.579C>T p.F193= | Silent (SNP) | VAF 138/401 reads (34%) | called by muse, mutect2, varscan2
- PPP1R26 | c.1515C>T p.S505= | Silent (SNP) | VAF 141/416 reads (34%) | catalogued as rs867300322; called by muse, mutect2
- PPP1R26 | c.1516C>T p.L506= | Silent (SNP) | VAF 141/414 reads (34%) | catalogued as rs752300589; called by muse, mutect2
- PRAMEF19 | c.364C>T p.L122= | Silent (SNP) | VAF 91/1045 reads (9%) | called by muse, mutect2
- PROKR2 | c.351G>A p.R117= | Silent (SNP) | VAF 145/400 reads (36%) | called by muse, mutect2, varscan2
- PRR23C | c.381C>T p.F127= | Silent (SNP) | VAF 177/491 reads (36%) | catalogued as COSV68827282; called by muse, mutect2, varscan2
- PRUNE2 | c.3354G>A p.V1118= | Silent (SNP) | VAF 136/212 reads (64%) | catalogued as COSV65043520; called by muse, mutect2, varscan2
- PTCHD3 | c.624C>T p.F208= | Silent (SNP) | VAF 156/279 reads (56%) | catalogued as rs1279965869, COSV71256250; called by muse, mutect2, varscan2
- QPRT | c.150C>T p.S50= | Silent (SNP) | VAF 227/611 reads (37%) | catalogued as COSV54879836; called by muse, mutect2, varscan2
- QSOX2 | c.540G>A p.T180= | Silent (SNP) | VAF 157/446 reads (35%) | catalogued as rs771678405, COSV62394407; called by muse, mutect2, varscan2
- RASGRF2 | c.1194C>T p.L398= | Silent (SNP) | VAF 243/440 reads (55%) | called by muse, mutect2, varscan2
- RBFOX3 | c.339C>T p.P113= | Silent (SNP) | VAF 137/386 reads (35%) | catalogued as rs758551578, COSV70559285; called by muse, mutect2, varscan2
- RGPD4 | c.3276C>T p.V1092= | Silent (SNP) | VAF 171/560 reads (31%) | catalogued as COSV100736430; called by muse, mutect2, varscan2
- RHBG | c.192C>T p.F64= | Silent (SNP) | VAF 290/453 reads (64%) | called by muse, mutect2, varscan2
- RIMS1 | c.3750G>A p.Q1250= | Silent (SNP) | VAF 118/287 reads (41%) | called by muse, mutect2, varscan2
- RIPOR3 | c.711G>A p.K237= | Silent (SNP) | VAF 127/302 reads (42%) | catalogued as COSV50410037; called by muse, mutect2, varscan2
- RNF180 | c.354C>T p.S118= | Silent (SNP) | VAF 251/355 reads (71%) | called by muse, mutect2, varscan2
- RPS6KA2 | c.225G>A p.L75= | Silent (SNP) | VAF 89/267 reads (33%) | called by muse, mutect2, varscan2
- RYR1 | c.1431C>T p.F477= | Silent (SNP) | VAF 104/277 reads (38%) | catalogued as rs1204983982; called by muse, mutect2, varscan2
- S1PR1 | c.579C>T p.T193= | Silent (SNP) | VAF 166/464 reads (36%) | catalogued as COSV59513118; called by muse, mutect2, varscan2
- SART3 | c.2007C>A p.I669= (on ENST00000228284; = p.I651= on NM_014706.4) | Silent (SNP) | VAF 138/381 reads (36%) | called by muse, mutect2, varscan2
- SDCCAG8 | c.2010C>T p.S670= | Silent (SNP) | VAF 469/755 reads (62%) | called by muse, mutect2, varscan2
- SERPINB11 | c.342G>A p.T114= | Silent (SNP) | VAF 105/269 reads (39%) | catalogued as rs751420424, COSV66956971; called by muse, mutect2, varscan2
- SH2D3C | c.501C>T p.D167= | Silent (SNP) | VAF 125/277 reads (45%) | catalogued as rs139326922; called by muse, mutect2, varscan2
- SIGLEC14 | c.666G>A p.V222= | Silent (SNP) | VAF 147/439 reads (33%) | called by muse, mutect2, varscan2
- SIN3B | c.2697C>T p.H899= | Silent (SNP) | VAF 134/309 reads (43%) | catalogued as COSV56131303; called by muse, mutect2, varscan2
- SLC1A6 | c.534C>T p.F178= | Silent (SNP) | VAF 135/361 reads (37%) | catalogued as rs924553349; called by muse, mutect2, varscan2
- SLC22A8 | c.1494G>A p.Q498= | Silent (SNP) | VAF 197/537 reads (37%) | called by muse, mutect2, varscan2
- SLC27A6 | c.1248G>A p.V416= | Silent (SNP) | VAF 82/197 reads (42%) | catalogued as rs1456746382, COSV99321957; called by muse, mutect2, varscan2
- SLFN13 | c.1302C>T p.F434= | Silent (SNP) | VAF 127/370 reads (34%) | called by muse, varscan2
- SMOC1 | c.954G>A p.G318= | Silent (SNP) | VAF 100/310 reads (32%) | catalogued as COSV100734755; called by muse, mutect2, varscan2
- SNX29 | c.2262C>T p.P754= | Silent (SNP) | VAF 150/408 reads (37%) | catalogued as rs202000492; called by muse, varscan2
- SPACA7 | c.183G>A p.L61= | Silent (SNP) | VAF 170/542 reads (31%) | catalogued as COSV52098162, COSV52103329; called by muse, mutect2
- SPARCL1 | c.402C>T p.L134= | Silent (SNP) | VAF 130/398 reads (33%) | catalogued as COSV99215853; called by muse, mutect2
- SPATA31A1 | c.1977G>A p.V659= | Silent (SNP) | VAF 239/740 reads (32%) | called by muse, mutect2, varscan2
- SPATS2L | c.1479C>T p.S493= | Silent (SNP) | VAF 196/550 reads (36%) | called by muse, mutect2, varscan2
- SPNS3 | c.495C>T p.F165= | Silent (SNP) | VAF 183/475 reads (39%) | catalogued as rs781205709, COSV61072742; called by muse, mutect2, varscan2
- SQOR | c.1299T>C p.G433= | Silent (SNP) | VAF 108/476 reads (23%) | called by muse, mutect2, varscan2
- STARD13 | c.2076C>T p.L692= (on ENST00000336934 / NM_001243476.3; = p.L574= on NM_052851.3) | Silent (SNP) | VAF 90/261 reads (34%) | catalogued as rs373241738, COSV55232274; called by muse, mutect2, varscan2
- STEAP4 | c.312C>T p.I104= | Silent (SNP) | VAF 261/448 reads (58%) | called by muse, mutect2, varscan2
- TANGO6 | c.3189C>T p.L1063= | Silent (SNP) | VAF 163/439 reads (37%) | called by muse, mutect2, varscan2
- TAS2R13 | c.732C>T p.F244= | Silent (SNP) | VAF 154/434 reads (35%) | catalogued as rs970977617; called by muse, mutect2, varscan2
- TENM2 | c.1092G>A p.L364= (on ENST00000518659 / NM_001122679.2; = p.L173= on NM_001080428.3) | Silent (SNP) | VAF 320/424 reads (75%) | catalogued as rs747399401, COSV69135949; called by muse, mutect2, varscan2
- TENM3 | c.2508C>T p.S836= | Silent (SNP) | VAF 149/410 reads (36%) | called by muse, mutect2, varscan2
- TET2 | c.1056C>T p.F352= | Silent (SNP) | VAF 146/400 reads (37%) | catalogued as COSV54422485; called by muse, mutect2
- TEX44 | c.582G>A p.E194= | Silent (SNP) | VAF 207/553 reads (37%) | called by muse, mutect2, varscan2
- TGM2 | c.81C>T p.C27= | Silent (SNP) | VAF 235/630 reads (37%) | catalogued as rs1416410878; called by muse, mutect2, varscan2
- TLL1 | c.831G>A p.L277= | Silent (SNP) | VAF 96/240 reads (40%) | called by muse, mutect2, varscan2
- TLR2 | c.1149G>A p.E383= | Silent (SNP) | VAF 160/340 reads (47%) | catalogued as rs1388257013; called by muse, mutect2, varscan2
- TMEM108 | c.1302C>T p.V434= | Silent (SNP) | VAF 186/450 reads (41%) | catalogued as rs779726153; called by muse, mutect2, varscan2
- TMEM132D | c.594C>T p.L198= | Silent (SNP) | VAF 199/619 reads (32%) | catalogued as COSV70606521; called by muse, mutect2, varscan2
- TMEM26 | c.873G>A p.A291= | Silent (SNP) | VAF 187/291 reads (64%) | catalogued as rs199546375; called by muse, mutect2, varscan2
- TNR | c.60C>T p.I20= | Silent (SNP) | VAF 499/752 reads (66%) | catalogued as COSV54878050; called by muse, mutect2, varscan2
- TOR1A | c.330C>T p.F110= | Silent (SNP) | VAF 160/506 reads (32%) | catalogued as rs1293414901, COSV61028743; called by muse, mutect2, varscan2
- TRIM9 | c.1710G>A p.G570= | Silent (SNP) | VAF 154/487 reads (32%) | called by muse, mutect2, varscan2
- TRPM2 | c.2811C>T p.F937= | Silent (SNP) | VAF 137/378 reads (36%) | catalogued as COSV55970830; called by muse, mutect2, varscan2
- TSPAN2 | c.12C>T p.F4= | Silent (SNP) | VAF 135/410 reads (33%) | called by muse, mutect2, varscan2
- UGT2B28 | c.1263G>A p.S421= | Silent (SNP) | VAF 95/338 reads (28%) | catalogued as rs751057671; called by muse, mutect2, varscan2
- UNC80 | c.882C>T p.S294= | Silent (SNP) | VAF 155/434 reads (36%) | catalogued as COSV99778759; called by muse, mutect2, varscan2
- USP6 | c.2679G>A p.E893= | Silent (SNP) | VAF 138/363 reads (38%) | catalogued as COSV51488894; called by muse, mutect2, varscan2
- VSTM2L | c.228C>T p.I76= | Silent (SNP) | VAF 187/565 reads (33%) | called by muse, mutect2, varscan2
- WDR64 | c.906A>C p.S302= | Silent (SNP) | VAF 101/505 reads (20%) | called by muse, mutect2, varscan2
- WDR90 | c.3957C>T p.S1319= | Silent (SNP) | VAF 213/550 reads (39%) | catalogued as rs200652650; called by muse, mutect2, varscan2
- XRCC3 | c.279C>T p.L93= | Silent (SNP) | VAF 193/572 reads (34%) | called by muse, mutect2, varscan2
- ZFP92 | c.813G>A p.K271= | Silent (SNP) | VAF 243/394 reads (62%) | catalogued as rs1556975025, COSV58599129; called by muse, mutect2, varscan2
- ZNF165 | c.774C>T p.I258= | Silent (SNP) | VAF 225/424 reads (53%) | called by muse, mutect2, varscan2
- ZNF536 | c.3555C>T p.T1185= | Silent (SNP) | VAF 178/512 reads (35%) | catalogued as rs373198343, COSV62830997; called by muse, mutect2, varscan2
- ZNF728 | c.126C>T p.F42= | Silent (SNP) | VAF 102/304 reads (34%) | called by muse, mutect2, varscan2
- ABCC3 | c.1635+23G>A | Intron (SNP) | VAF 210/548 reads (38%) | called by muse, mutect2, varscan2
- AC092718.9 | chr16:81156945 C>T | 3'Flank (SNP) | VAF 121/350 reads (35%) | called by muse, mutect2, varscan2
- AL118558.3 | n.240C>T | RNA (SNP) | VAF 127/367 reads (35%) | catalogued as rs1475500288; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73826091 C>T | 5'Flank (SNP) | VAF 124/358 reads (35%) | called by muse, mutect2, varscan2
- ANKRD18A | chr9:38571179 GG>T | 3'Flank (DEL) | VAF 37/150 reads (25%) | called by pindel, varscan2*
- CAMKK1 | c.685+159C>T | Intron (SNP) | VAF 76/223 reads (34%) | called by muse, mutect2, varscan2
- CYP11B1 | c.239+127G>A | Intron (SNP) | VAF 436/674 reads (65%) | called by muse, mutect2, varscan2
- DCN | c.211+801G>T | Intron (SNP) | VAF 104/291 reads (36%) | called by muse, mutect2, varscan2
- FAM13C | c.508-59C>T | Intron (SNP) | VAF 163/255 reads (64%) | called by muse, mutect2, varscan2
- GRAMD1A | chr19:34996112 G>A | 5'Flank (SNP) | VAF 158/405 reads (39%) | called by muse, mutect2, varscan2
- IGSF22 | c.2095+1506G>A | Intron (SNP) | VAF 142/350 reads (41%) | called by muse, mutect2, varscan2
- LINC02767 | n.3867G>A | RNA (SNP) | VAF 383/581 reads (66%) | called by muse, mutect2, varscan2
- MIR9-1HG | n.424C>T | RNA (SNP) | VAF 153/738 reads (21%) | called by muse, mutect2, varscan2
- MYCBP2 | c.*12C>T | 3'UTR (SNP) | VAF 117/315 reads (37%) | catalogued as rs372847961; called by muse, mutect2, varscan2
- NEB | c.8890-2876G>A | Intron (SNP) | VAF 127/405 reads (31%) | catalogued as rs375811851; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRSS3 | c.-191C>T | 5'UTR (SNP) | VAF 150/480 reads (31%) | catalogued as COSV61553106; called by muse, varscan2
- SLCO1B3-SLCO1B7 | c.1866-15064G>A | Intron (SNP) | VAF 68/229 reads (30%) | catalogued as rs756696482, COSV67441938; called by muse, mutect2, varscan2
- SUSD4 | c.725-5684C>T | Intron (SNP) | VAF 410/623 reads (66%) | catalogued as COSV100663486; called by muse, mutect2, varscan2
- TIA1 | c.*3091C>T | 3'UTR (SNP) | VAF 123/288 reads (43%) | called by muse, mutect2, varscan2
- TTN | c.10360+1094C>T | Intron (SNP) | VAF 78/195 reads (40%) | catalogued as rs1294088345; called by muse, varscan2
